Somatic mutation profile of tumor specimen TCGA-W5-AA2R-01A (aliquot TCGA-W5-AA2R-01A-11D-A417-09) from TCGA case TCGA-W5-AA2R, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 77.7 years (28,367 days).
Specimen TCGA-W5-AA2R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30cab568-9509-44a7-9a76-13ecabc285f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2R-10A (Blood Derived Normal), aliquot TCGA-W5-AA2R-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3d4ce1e-167a-4ceb-aa86-05b7ad94aece

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CREB3L4 | c.904_906del p.L302del | In Frame Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs766050808; called by pindel, varscan2
- F13A1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs941140530; called by muse, mutect2, varscan2
- HLA-A | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.988); catalogued as rs749604425, COSV65136444, COSV65138215; called by muse, mutect2
- LPP | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288090501, COSV57082535; called by muse, mutect2, varscan2
- ELAPOR2 | c.3022G>C p.A1008P (on ENST00000450689 / NM_001142749.3; = p.A841P on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HTRA4 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); called by mutect2, varscan2
- LIAS | c.624G>C p.Q208H (on ENST00000261434 / NM_001363700.2; = p.Q311H on NM_006859.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MAOB | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METTL8 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PSEN2 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SASS6 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31D1 | c.3118A>G p.T1040A | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TMIGD1 | c.786-1G>T p.X262_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- AGTR2 | c.234T>C p.V78= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- GALNT14 | c.552T>A p.I184= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- NCK2 | c.39C>T p.Y13= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1203928555; called by muse, mutect2, varscan2
- PARGP1 | n.1723T>C | RNA (SNP) | VAF 102/439 reads (23%) | called by muse, mutect2, varscan2
